Somatic mutation profile of tumor specimen TARGET-10-PAPBPC-09A (aliquot TARGET-10-PAPBPC-09A-01D) from TARGET case TARGET-10-PAPBPC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,567 days).
Specimen TARGET-10-PAPBPC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20a5d4c2-43e8-43cd-8c11-239fd27d8561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBPC-10A (Blood Derived Normal), aliquot TARGET-10-PAPBPC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2a38df0-b020-4455-8afc-b7649a5680d5

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDI2 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1165431797; called by muse, mutect2
- NOL4 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as rs1309890459, COSV52342053; called by muse, mutect2
- FBXL19 | c.1032C>A p.D344E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.323); called by muse, mutect2
- KCNG2 | c.597G>C p.M199I | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- LAMB4 | c.1361-1G>T p.X454_splice | Splice Site (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- NIM1K | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP160 | c.4224G>T p.L1408= | Splice Region (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- PER2 | c.2117G>T p.G706V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ADAMTS20 | c.5004G>T p.V1668= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV101239011; called by muse, mutect2
- CA4 | c.891C>A p.A297= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- DAAM2 | c.1770C>T p.D590= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs377713628; called by muse, mutect2, varscan2
- RAB2A | c.119-2052A>G | Intron (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
